Somatic mutation profile of tumor specimen MMRF_2630_1_BM_CD138pos (aliquot MMRF_2630_1_BM_CD138pos_T1_KHS5U_L13302) from MMRF case MMRF_2630, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.8 years (21,481 days).
Specimen MMRF_2630_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6cd70ff-6280-4774-8d69-466ac593d2e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2630_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2630_1_PB_WBC_C3_KHS5U_L13303; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0d78a15-77d5-4d1f-895a-7819fdb0d57f

The open-access MAF lists 132 somatic variants for this specimen: 53 protein-altering or splice-affecting, 20 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, 3'UTR 30, Silent 20, Intron 15, 3'Flank 6, 5'UTR 4, Splice Region 4, 5'Flank 2, RNA 2, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAND1 | c.2840C>G p.T947S | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.406); catalogued as COSV73389792; called by muse, mutect2, varscan2
- CDH6 | c.1334T>G p.L445R | Missense Mutation (SNP) | VAF 73/113 reads (65%) | SIFT tolerated (0.23); PolyPhen benign (0.139); catalogued as COSV54077754; called by muse, mutect2, varscan2
- DISP3 | c.3519A>G p.I1173M | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.828); catalogued as rs912863997; called by muse, mutect2, varscan2
- DOK6 | c.411G>A p.E137= | Splice Region (SNP) | VAF 67/297 reads (23%) | catalogued as COSV66927278; called by muse, mutect2, varscan2
- DST | c.9241G>A p.E3081K | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as rs753725962; called by muse, mutect2, varscan2
- EARS2 | c.655A>G p.I219V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.479); catalogued as rs1425710964; called by muse, mutect2, varscan2
- IGHV2-70 | c.71G>C p.R24T | Missense Mutation (SNP) | VAF 50/56 reads (89%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs10144703; called by muse, varscan2
- IGLV1-44 | c.303G>C p.E101D | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.076); catalogued as rs769040748; called by muse, varscan2
- KAZN | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 87/232 reads (38%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.676); catalogued as rs200807421; called by muse, mutect2, varscan2
- MOCOS | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 15/483 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1282022057, COSV54345359; called by muse, mutect2
- RAD23B | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.321); catalogued as rs1386224950; called by muse, mutect2, varscan2
- TDRD3 | c.943A>C p.N315H | Missense Mutation (SNP) | VAF 104/129 reads (81%) | SIFT tolerated (0.11); PolyPhen benign (0.376); catalogued as rs76903991, COSV52159262; called by muse, mutect2, varscan2
- VPS35L | c.1705T>C p.F569L | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs374146026; called by muse, mutect2, varscan2
- VPS53 | c.1321G>A p.G441R (on ENST00000571805 / NM_001366253.2; = p.G412R on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs768091538; called by muse, mutect2, varscan2
- VWA2 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.071); catalogued as rs765092046, COSV53909821; called by muse, mutect2, varscan2
- ADAM2 | c.1843G>T p.D615Y | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- AHNAK2 | c.1503G>T p.E501D | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- AP2M1 | c.186C>A p.N62K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ATAD3A | c.1119A>T p.E373D | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- BPIFA3 | c.77G>T p.W26L | Missense Mutation (SNP) | VAF 107/238 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- CCL4 | c.191+8T>C | Splice Region (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- CEP162 | c.1662A>G p.K554= | Splice Region (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
- DDX42 | c.262T>G p.L88V | Missense Mutation (SNP) | VAF 101/233 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- DIS3 | c.2251_2286del p.A751_F762del | In Frame Del (DEL) | VAF 25/42 reads (60%) | called by mutect2, pindel
- DPYD | c.2170G>T p.A724S | Missense Mutation (SNP) | VAF 68/149 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- EGFLAM | c.1630A>G p.R544G | Missense Mutation (SNP) | VAF 76/279 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.079); called by muse, mutect2
- FZD9 | c.727T>C p.F243L | Missense Mutation (SNP) | VAF 228/332 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); called by muse, mutect2
- FZD9 | c.758T>A p.F253Y | Missense Mutation (SNP) | VAF 262/392 reads (67%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2
- FZD9 | c.1402T>A p.Y468N | Missense Mutation (SNP) | VAF 306/450 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FZD9 | c.1507T>A p.S503T | Missense Mutation (SNP) | VAF 247/355 reads (70%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); called by muse, varscan2
- GPR143 | c.768T>C p.C256= | Splice Region (SNP) | VAF 22/25 reads (88%) | called by muse, mutect2, varscan2
- IGLV7-46 | c.219C>G p.S73R | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- KCNG2 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- LATS1 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- LRRC36 | c.2167G>A p.G723R | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MIB1 | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 89/296 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MYH2 | c.1445A>T p.N482I | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NCKAP5 | c.2102C>G p.T701S | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NFKBIA | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP13 | c.250G>C p.V84L | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); called by muse, mutect2
- PRLHR | c.910G>C p.D304H | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RNF43 | c.939G>C p.M313I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.39); called by muse, mutect2
- RP1 | c.1217C>A p.A406D | Missense Mutation (SNP) | VAF 102/229 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RYR3 | c.5635A>C p.N1879H | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- SLC22A25 | c.1303G>T p.V435L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SLC27A1 | c.654C>A p.H218Q | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLCO1A2 | c.431A>C p.Q144P | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMX3 | c.1280A>C p.K427T | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM72 | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2
- USP22 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.71); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- WDR3 | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- ZC3H18 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- ZNF585A | c.1900T>G p.Y634D (on ENST00000292841 / NM_001288800.2; = p.Y579D on NM_152655.3) | Missense Mutation (SNP) | VAF 118/392 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- CHST6 | c.456G>A p.L152= | Silent (SNP) | VAF 88/188 reads (47%) | catalogued as COSV100178611; called by muse, mutect2, varscan2
- DDX39A | c.348G>A p.L116= | Silent (SNP) | VAF 67/228 reads (29%) | catalogued as rs144413770; called by muse, mutect2, varscan2
- DHFR | c.81G>A p.P27= | Silent (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- IFNA8 | c.342G>A p.Q114= | Silent (SNP) | VAF 68/239 reads (28%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.339G>C p.T113= | Silent (SNP) | VAF 42/58 reads (72%) | called by muse, varscan2
- IGHV2-70D | c.273C>A p.S91= | Silent (SNP) | VAF 84/107 reads (79%) | called by muse, varscan2
- IGHV2-70D | c.219T>C p.D73= | Silent (SNP) | VAF 94/113 reads (83%) | called by muse, varscan2
- KCNG2 | c.1332G>C p.S444= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV100302028; called by muse, mutect2
- MIA3 | c.4998T>C p.S1666= | Silent (SNP) | VAF 18/152 reads (12%) | called by muse, mutect2, varscan2
- OR4D5 | c.744C>T p.T248= | Silent (SNP) | VAF 81/248 reads (33%) | catalogued as rs1377610977; called by muse, mutect2, varscan2
- PCDH10 | c.3066G>T p.L1022= | Silent (SNP) | VAF 22/58 reads (38%) | called by muse, mutect2, varscan2
- PCDHGB1 | c.1854C>A p.R618= | Silent (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- RASIP1 | c.1065C>T p.D355= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV55804367; called by muse, mutect2, varscan2
- RYR1 | c.12441C>T p.T4147= | Silent (SNP) | VAF 87/303 reads (29%) | catalogued as rs1416111897; called by muse, mutect2, varscan2
- SLC39A13 | c.660C>T p.L220= | Silent (SNP) | VAF 88/201 reads (44%) | catalogued as rs1458828854; called by muse, mutect2, varscan2
- TNRC6C | c.120G>A p.G40= | Silent (SNP) | VAF 35/75 reads (47%) | catalogued as rs544038591; called by muse, mutect2, varscan2
- TOX3 | c.1047G>A p.S349= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as rs1050741893, COSV54867155; called by muse, mutect2, varscan2
- VPS13D | c.4560T>C p.S1520= | Silent (SNP) | VAF 15/67 reads (22%) | called by muse, mutect2, varscan2
- WDR17 | c.2091A>G p.R697= | Silent (SNP) | VAF 76/178 reads (43%) | called by muse, mutect2, varscan2
- ZFHX4 | c.6357A>G p.L2119= | Silent (SNP) | VAF 34/123 reads (28%) | called by muse, mutect2, varscan2
- ABLIM1 | chr10:114431829 G>A | 3'Flank (SNP) | VAF 53/131 reads (40%) | called by muse, mutect2, varscan2
- ACTG1 | c.363+77A>G | Intron (SNP) | VAF 24/46 reads (52%) | catalogued as rs782086873, COSV59509516; called by muse, mutect2, varscan2
- AL132796.2 | n.315G>T | RNA (SNP) | VAF 68/76 reads (89%) | catalogued as rs1292809970; called by muse, mutect2, varscan2
- ANKRD34B | c.*413T>A | 3'UTR (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- AP3B1 | c.-54C>T | 5'UTR (SNP) | VAF 45/147 reads (31%) | called by muse, mutect2, varscan2
- C11orf68 | c.*422G>C | 3'UTR (SNP) | VAF 27/122 reads (22%) | catalogued as COSV56989103; called by muse, mutect2, varscan2
- C20orf202 | c.*1160G>T | 3'UTR (SNP) | VAF 9/15 reads (60%) | called by muse, varscan2
- C4orf50 | c.*1910G>A | 3'UTR (SNP) | VAF 13/60 reads (22%) | catalogued as rs898225785; called by muse, mutect2, varscan2
- C9orf153 | c.*17G>T | 3'UTR (SNP) | VAF 85/221 reads (38%) | called by muse, mutect2, varscan2
- CAST | c.75+539G>A | Intron (SNP) | VAF 15/44 reads (34%) | catalogued as rs1239075950; called by muse, mutect2, varscan2
- CITED2 | c.*579_*580insTATT | 3'UTR (INS) | VAF 5/32 reads (16%) | called by mutect2, pindel, varscan2
- DBX2 | chr12:45051132 G>T | 5'Flank (SNP) | VAF 36/85 reads (42%) | called by muse, mutect2, varscan2
- DCLK1 | c.*816C>T | 3'UTR (SNP) | VAF 30/34 reads (88%) | called by muse, mutect2, varscan2
- DHFR2 | c.*2209A>T | 3'UTR (SNP) | VAF 157/331 reads (47%) | called by mutect2, varscan2
- DHX29 | c.2994-14A>C | Intron (SNP) | VAF 18/62 reads (29%) | called by muse, varscan2
- DYNC1LI1 | c.*764T>A | 3'UTR (SNP) | VAF 28/73 reads (38%) | called by muse, mutect2, varscan2
- EMC10 | c.*505C>A | 3'UTR (SNP) | VAF 20/93 reads (22%) | called by muse, mutect2, varscan2
- ERCC8 | c.399+24G>T | Intron (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- ERLIN1 | chr10:100151736 C>T | 3'Flank (SNP) | VAF 26/109 reads (24%) | called by muse, mutect2, varscan2
- FMN1 | c.1867+2765G>C | Intron (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- FO393408.1 | n.17G>A | RNA (SNP) | VAF 22/23 reads (96%) | catalogued as rs1263901751; called by muse, mutect2, varscan2
- FOXP1 | c.*2227T>A | 3'UTR (SNP) | VAF 47/105 reads (45%) | called by muse, mutect2, varscan2
- FZD9 | c.*273T>G | 3'UTR (SNP) | VAF 30/46 reads (65%) | called by muse, mutect2, varscan2
- GPR85 | c.*737A>C | 3'UTR (SNP) | VAF 16/137 reads (12%) | called by muse, mutect2, varscan2
- HCN4 | c.*1573G>A | 3'UTR (SNP) | VAF 6/147 reads (4%) | called by muse, mutect2
- IFIT5 | c.*31T>G | 3'UTR (SNP) | VAF 103/217 reads (47%) | called by muse, mutect2, varscan2
- JAKMIP2 | c.-272A>G | 5'UTR (SNP) | VAF 62/120 reads (52%) | catalogued as rs908141103, COSV54601436, COSV54607886; called by muse, varscan2
- KCNAB2 | c.78-141A>T | Intron (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- KCNV1 | chr8:109966574 T>G | 3'Flank (SNP) | VAF 44/88 reads (50%) | called by muse, mutect2, varscan2
- KRT15 | chr17:41520342 del G | 5'Flank (DEL) | VAF 8/94 reads (9%) | called by mutect2, pindel
- LIMS1 | chr2:108686564 G>C | 3'Flank (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- LRRC59 | c.*1234T>A | 3'UTR (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- MCOLN1 | c.984+18T>G | Intron (SNP) | VAF 28/99 reads (28%) | called by muse, mutect2, varscan2
- MKNK1 | c.-2-2653C>A | Intron (SNP) | VAF 130/342 reads (38%) | called by muse, varscan2
- NAGA | c.*1539G>A | 3'UTR (SNP) | VAF 49/120 reads (41%) | called by muse, mutect2, varscan2
- NCAM2 | c.*1407G>C | 3'UTR (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- NFASC | c.*3684C>A | 3'UTR (SNP) | VAF 138/236 reads (58%) | called by muse, mutect2, varscan2
- NOL11 | c.1403+37T>C | Intron (SNP) | VAF 72/156 reads (46%) | called by muse, mutect2, varscan2
- NTPCR | c.*160A>G | 3'UTR (SNP) | VAF 26/86 reads (30%) | called by muse, mutect2, varscan2
- PARP16 | c.-332T>C | 5'UTR (SNP) | VAF 62/136 reads (46%) | called by muse, mutect2, varscan2
- PRTG | c.*1002T>C | 3'UTR (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- PTPN21 | c.*678A>G | 3'UTR (SNP) | VAF 57/62 reads (92%) | called by muse, mutect2, varscan2
- RAB30 | chr11:82980862 G>T | 3'Flank (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
- RAB30 | chr11:82980958 A>C | 3'Flank (SNP) | VAF 42/121 reads (35%) | called by muse, mutect2, varscan2
- RERG | c.*832A>C | 3'UTR (SNP) | VAF 35/67 reads (52%) | called by muse, mutect2, varscan2
- RNF125 | c.*2309A>T | 3'UTR (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2
- SERP2 | c.158-6886G>A | Intron (SNP) | VAF 12/16 reads (75%) | called by muse, mutect2, varscan2
- SLMAP | c.1336+4314G>A | Intron (SNP) | VAF 42/103 reads (41%) | called by muse, mutect2, varscan2
- SMARCE1 | c.*300G>T | 3'UTR (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- TANK | c.-49-18G>A | Intron (SNP) | VAF 98/230 reads (43%) | called by muse, mutect2, varscan2
- TCP11L2 | c.772+897T>G | Intron (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2, varscan2
- TMEM214 | c.1152+51C>T | Intron (SNP) | VAF 53/131 reads (40%) | catalogued as rs764755136; called by muse, mutect2, varscan2
- TUSC3 | c.*1400A>C | 3'UTR (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2, varscan2
- UNC5C | c.*6490A>T | 3'UTR (SNP) | VAF 35/105 reads (33%) | catalogued as rs1470713807; called by muse, mutect2, varscan2
- VSX2 | c.*826G>T | 3'UTR (SNP) | VAF 216/250 reads (86%) | called by muse, mutect2, varscan2
- WDR97 | c.*2008G>T | 3'UTR (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2
- YPEL5 | c.*1264T>A | 3'UTR (SNP) | VAF 34/88 reads (39%) | called by muse, mutect2, varscan2
- ZFC3H1 | c.1015+440T>G | Intron (SNP) | VAF 5/120 reads (4%) | called by muse, mutect2
- ZNF736 | c.-163T>G | 5'UTR (SNP) | VAF 37/222 reads (17%) | called by muse, mutect2, varscan2
